Somatic mutation profile of cancer-model specimen HCM-CSHL-0322-C20-85A (3D Organoid; aliquot HCM-CSHL-0322-C20-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-CSHL-0322-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 69.1 years (25,229 days).
Specimen HCM-CSHL-0322-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3305831-f94f-4bb4-becf-63b4e8e27df7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0322-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0322-C20-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47089fac-8e65-4661-b2e7-a36655187e5d

The open-access MAF lists 140 somatic variants for this specimen: 97 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 37, Nonsense Mutation 7, Intron 4, Splice Region 3, Frame Shift Ins 2, Frame Shift Del 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 203/328 reads (62%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 76/230 reads (33%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 174/272 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 369/369 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 197/418 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); catalogued as rs758992299, COSV53124024; called by muse, mutect2, varscan2
- ADD2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 169/332 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs141431061; called by muse, mutect2, varscan2
- ADGRL3 | c.3016A>G p.I1006V (on ENST00000506720 / NM_001322402.2; = p.I938V on NM_015236.6) | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.531); catalogued as rs372437409; called by muse, mutect2, varscan2
- AGT | c.314T>C p.M105T | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs933260912; called by muse, mutect2, varscan2
- ARHGEF10 | c.3961C>T p.R1321C (on ENST00000398564; = p.R1296C on NM_014629.4) | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs747279075, COSV50683984; called by muse, mutect2, varscan2
- ARSI | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 317/466 reads (68%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs541439593; called by muse, mutect2, varscan2
- ATG7 | c.1625A>G p.N542S | Missense Mutation (SNP) | VAF 195/303 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as rs752093920; called by muse, mutect2, varscan2
- BMP15 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 308/688 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868942078, COSV53139709; called by muse, mutect2, varscan2
- BRINP3 | c.1669A>G p.I557V | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as COSV104427470; called by muse, mutect2
- BTNL3 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201534771, COSV61565707, COSV61566065; called by muse, mutect2, varscan2
- CACNA1H | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 121/651 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.819); catalogued as rs1332969846; called by muse, mutect2, varscan2
- CHRM2 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV57775959; called by muse, mutect2, varscan2
- CLDN17 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767649088, COSV99729012; called by muse, mutect2, varscan2
- COL17A1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768224335, COSV100793172; called by muse, varscan2
- COL19A1 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 70/331 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1247810382; called by muse, mutect2, varscan2
- CSMD3 | c.7324C>T p.R2442* (on ENST00000297405 / NM_001363185.1; = p.R2338* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 68/246 reads (28%) | catalogued as rs995871749, COSV52274871; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 83/161 reads (52%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- ERBB4 | c.2418G>T p.E806D | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775875805, COSV100723582, COSV100725817; called by muse, mutect2, varscan2
- ESPNL | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 179/609 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs570616030, COSV58032853; called by muse, mutect2, varscan2
- FIBCD1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 261/398 reads (66%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs1392793644, COSV53395768; called by muse, mutect2, varscan2
- FRMD8 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 189/588 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.385); catalogued as rs776360172; called by muse, mutect2, varscan2
- GABRB1 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 136/390 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs748097369, COSV54984293; called by muse, mutect2, varscan2
- GALNT9 | c.1328G>A p.R443H (on ENST00000328957 / NM_001122636.2; = p.R77H on NM_021808.3) | Missense Mutation (SNP) | VAF 250/395 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs763432318, COSV61095686; called by muse, mutect2, varscan2
- GPR50 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 183/398 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.729); catalogued as rs1157091999; called by muse, varscan2
- GRIK1 | c.2755dup p.I919Nfs*8 (on ENST00000327783 / NM_001330994.2; = p.I875Nfs*8 on NM_175611.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 57/206 reads (28%) | catalogued as rs1200907182; called by mutect2, varscan2
- HNF4A | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 346/443 reads (78%) | catalogued as rs1413742263, COSV57381479; called by muse, mutect2, varscan2
- HOXD4 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 204/817 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.229); catalogued as COSV60460322; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- IGHE | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 211/648 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs782170045; called by muse, mutect2, varscan2
- KCNQ5 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV59669471; called by muse, mutect2, varscan2
- LIPE | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 273/558 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.197); catalogued as rs1296210753; called by muse, mutect2, varscan2
- LRP1B | c.11317A>G p.K3773E | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.055); catalogued as rs760824823; called by muse, mutect2, varscan2
- PABPC4L | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs866386625, COSV101413742; called by muse, mutect2, varscan2
- PADI1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 102/328 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.431); catalogued as rs200141204, COSV64937802; called by muse, mutect2, varscan2
- PCDH17 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 127/533 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs760953125, COSV64976241, COSV64979321; called by muse, mutect2, varscan2
- PDGFRA | c.3009G>A p.W1003* | Nonsense Mutation (SNP) | VAF 105/315 reads (33%) | catalogued as COSV57272140; called by muse, mutect2, varscan2
- PLA1A | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773067658; called by muse, mutect2, varscan2
- PRKCG | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 195/385 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV54724264; called by muse, mutect2, varscan2
- PRKCG | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 114/460 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54730911; called by muse, mutect2, varscan2
- PROM1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 157/264 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs375364598; called by muse, mutect2, varscan2
- RABL6 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 161/252 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV99051474; called by mutect2, varscan2
- RAI14 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs576334657, COSV54299098; called by muse, mutect2, varscan2
- RHBDD2 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 123/508 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as rs782706762, COSV50086897; called by muse, mutect2, varscan2
- SDK1 | c.4439C>G p.P1480R | Missense Mutation (SNP) | VAF 207/500 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770812300; called by muse, mutect2, varscan2
- SLC9C1 | c.2161C>A p.R721S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV59890424; called by muse, mutect2, varscan2
- SPEM2 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 137/471 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs771101898, COSV60366098; called by muse, mutect2, varscan2
- TNIP1 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 136/413 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs139724991; called by muse, mutect2, varscan2
- VEGFC | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 129/184 reads (70%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs769325515; called by muse, mutect2, varscan2
- ZNF442 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 93/399 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs770731530; called by muse, mutect2, varscan2
- ZNRF4 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 151/677 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199529322; called by muse, mutect2, varscan2
- ABCB11 | c.3151_3152insG p.F1051Cfs*19 | Frame Shift Ins (INS) | VAF 83/403 reads (21%) | called by mutect2, pindel, varscan2
- ACSM4 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 97/414 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANK3 | c.4036G>C p.E1346Q (on ENST00000280772 / NM_001320874.2; = p.E480Q on NM_001149.3) | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCR3 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); called by muse, mutect2
- CTCFL | c.1636T>C p.Y546H | Missense Mutation (SNP) | VAF 116/616 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.022); called by muse, mutect2
- DCLK1 | c.1385A>T p.Y462F | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- DENND4B | c.3262C>A p.P1088T | Missense Mutation (SNP) | VAF 180/518 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by mutect2, varscan2
- DMRTB1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 177/516 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.7052_7053del p.S2351Cfs*4 | Frame Shift Del (DEL) | VAF 92/294 reads (31%) | called by mutect2, pindel, varscan2
- FBN1 | c.3404G>T p.S1135I | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN2 | c.7512C>A p.Y2504* | Nonsense Mutation (SNP) | VAF 68/206 reads (33%) | called by muse, mutect2, varscan2
- FLII | c.3147G>T p.Q1049H | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FRMPD1 | c.3860T>C p.I1287T | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRC6A | c.2351T>G p.I784S | Missense Mutation (SNP) | VAF 86/330 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- HNRNPCL2 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 279/444 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IDO2 | c.332T>C p.L111P (on ENST00000389060; = p.L124P on NM_194294.2) | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT5B | c.1174+5G>C | Splice Region (SNP) | VAF 51/167 reads (31%) | called by muse, mutect2, varscan2
- LAG3 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 119/586 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- LIFR | c.2467A>C p.K823Q | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- LRRC7 | c.3347G>T p.G1116V (on ENST00000651989 / NM_001370785.2; = p.G1083V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- MYO1H | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEU2 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NLRP1 | c.1263G>T p.E421D | Missense Mutation (SNP) | VAF 305/305 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NOL6 | c.3016G>C p.D1006H | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUDCD1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PARP10 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 165/515 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- PCNT | c.7876T>A p.S2626T | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCNT | c.7877C>A p.S2626Y | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- RARS2 | c.1232T>A p.I411N | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RRAGA | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 170/266 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- RTL3 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 26/715 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- SATB1 | c.753T>A p.V251= | Splice Region (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- SCEL | c.219C>T p.D73= | Splice Region (SNP) | VAF 15/401 reads (4%) | called by muse, mutect2
- SCN9A | c.5429A>G p.D1810G (on ENST00000303354; = p.D1799G on NM_002977.3) | Missense Mutation (SNP) | VAF 188/383 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SKI | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 162/516 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SLITRK1 | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 49/584 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- SYTL3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 162/368 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBA1 | c.1360C>A p.Q454K | Missense Mutation (SNP) | VAF 99/499 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- USH2A | c.536T>A p.I179K | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- USP9X | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 120/308 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WWP2 | c.1874G>C p.G625A | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF335 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 164/917 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZNF667 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 216/433 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.13269C>T p.D4423= | Silent (SNP) | VAF 109/345 reads (32%) | catalogued as rs202130765, COSV60909433; called by muse, mutect2, varscan2
- ALYREF | c.606A>G p.V202= | Silent (SNP) | VAF 11/375 reads (3%) | called by muse, mutect2
- AP2A1 | c.1731G>A p.Q577= | Silent (SNP) | VAF 181/781 reads (23%) | catalogued as COSV100756200; called by muse, mutect2, varscan2
- BCL9L | c.1833A>G p.V611= | Silent (SNP) | VAF 165/664 reads (25%) | catalogued as COSV52683147; called by muse, mutect2, varscan2
- CACNA1A | c.255C>T p.N85= | Silent (SNP) | VAF 183/388 reads (47%) | catalogued as rs1285665891, COSV100802754; called by muse, mutect2, varscan2
- CACNA1E | c.1692G>A p.T564= | Silent (SNP) | VAF 111/347 reads (32%) | catalogued as rs372308100; called by muse, mutect2, varscan2
- CFAP77 | c.906G>A p.R302= | Silent (SNP) | VAF 134/417 reads (32%) | catalogued as rs758982709; called by muse, mutect2, varscan2
- COL6A5 | c.1851C>T p.C617= | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as rs961502121; called by muse, mutect2, varscan2
- CRX | c.789C>T p.P263= | Silent (SNP) | VAF 133/547 reads (24%) | catalogued as rs550083287, CD013149, COSV55760174; called by muse, mutect2, varscan2
- CTSG | c.450C>T p.V150= | Silent (SNP) | VAF 148/490 reads (30%) | called by muse, mutect2, varscan2
- DRC1 | c.1896C>T p.F632= | Silent (SNP) | VAF 81/292 reads (28%) | catalogued as rs748628980, COSV55522594; called by muse, mutect2, varscan2
- ELOA3C | c.771C>T p.L257= | Silent (SNP) | VAF 78/3657 reads (2%) | called by muse, mutect2
- FGD1 | c.1881G>T p.R627= | Silent (SNP) | VAF 109/433 reads (25%) | catalogued as rs891555776; called by muse, mutect2, varscan2
- FUT3 | c.603G>A p.K201= | Silent (SNP) | VAF 327/670 reads (49%) | called by muse, mutect2, varscan2
- GDF10 | c.861C>T p.R287= | Silent (SNP) | VAF 201/587 reads (34%) | catalogued as rs1292525086; called by muse, mutect2, varscan2
- GRIN3A | c.1785C>T p.F595= | Silent (SNP) | VAF 86/287 reads (30%) | catalogued as rs369210508; called by muse, mutect2
- HERC5 | c.2622C>T p.N874= | Silent (SNP) | VAF 98/138 reads (71%) | catalogued as rs762515665, COSV52037656, COSV52037916; called by muse, mutect2, varscan2
- KCNA4 | c.1641G>A p.A547= | Silent (SNP) | VAF 113/326 reads (35%) | catalogued as rs368797575, COSV100069314; called by muse, mutect2, varscan2
- KIAA1755 | c.1506C>G p.S502= | Silent (SNP) | VAF 27/521 reads (5%) | catalogued as COSV99641912; called by muse, mutect2
- LINGO1 | c.802C>T p.L268= | Silent (SNP) | VAF 23/233 reads (10%) | called by muse, mutect2, varscan2
- LRP1B | c.5019G>A p.T1673= | Silent (SNP) | VAF 84/383 reads (22%) | catalogued as rs373983727; called by muse, mutect2, varscan2
- LTBP2 | c.3609C>T p.C1203= | Silent (SNP) | VAF 109/346 reads (32%) | catalogued as rs778364270, COSV56206477; called by muse, mutect2, varscan2
- MAP2 | c.3399T>C p.S1133= | Silent (SNP) | VAF 29/350 reads (8%) | called by muse, mutect2
- MAP2K1 | c.396G>A p.A132= | Silent (SNP) | VAF 70/132 reads (53%) | catalogued as rs139364105, COSV61073184; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH7 | c.3483C>T p.I1161= | Silent (SNP) | VAF 89/410 reads (22%) | catalogued as rs778909719, COSV100805799; called by muse, mutect2, varscan2
- MYOM2 | c.3142C>A p.R1048= | Silent (SNP) | VAF 87/178 reads (49%) | catalogued as COSV50757394; called by muse, mutect2, varscan2
- NPAS2 | c.1479A>T p.A493= | Silent (SNP) | VAF 16/509 reads (3%) | called by muse, mutect2
- OR4C5 | c.672T>C p.S224= | Silent (SNP) | VAF 89/315 reads (28%) | catalogued as rs762231003; called by muse, mutect2, varscan2
- OR4K3 | c.750T>C p.S250= | Silent (SNP) | VAF 64/443 reads (14%) | called by muse, mutect2, varscan2
- SFRP4 | c.279T>C p.P93= | Silent (SNP) | VAF 154/565 reads (27%) | called by muse, mutect2, varscan2
- TAF11L14 | c.450T>C p.V150= | Silent (SNP) | VAF 54/240 reads (23%) | called by muse, mutect2, varscan2
- THSD7A | c.4341G>A p.P1447= | Silent (SNP) | VAF 91/401 reads (23%) | catalogued as rs762226111, COSV70267009; called by muse, mutect2, varscan2
- TTN | c.1449C>T p.A483= | Silent (SNP) | VAF 189/401 reads (47%) | catalogued as rs141617218; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- VCAN | c.2670T>C p.G890= | Silent (SNP) | VAF 12/271 reads (4%) | called by muse, mutect2
- VWA3B | c.3210C>T p.Y1070= | Silent (SNP) | VAF 104/366 reads (28%) | catalogued as rs749665421, COSV69034143; called by muse, mutect2, varscan2
- ZBTB43 | c.588C>A p.P196= | Silent (SNP) | VAF 16/388 reads (4%) | called by muse, mutect2
- ZFR2 | c.162G>A p.P54= | Silent (SNP) | VAF 131/643 reads (20%) | catalogued as rs756593762, COSV53603470; called by muse, mutect2, varscan2
- BMP2 | c.-678C>G | 5'UTR (SNP) | VAF 165/968 reads (17%) | catalogued as rs1312128175; called by muse, mutect2, varscan2
- GTF2H1 | c.1053+103T>A | Intron (SNP) | VAF 77/236 reads (33%) | called by muse, mutect2, varscan2
- HAPLN3 | c.-48+2450G>T | Intron (SNP) | VAF 20/420 reads (5%) | called by muse, mutect2
- OBSCN | c.11659+4934G>A | Intron (SNP) | VAF 129/398 reads (32%) | catalogued as rs573702782, COSV99476137; called by muse, mutect2, varscan2
- SLC12A5 | c.121+1511C>T | Intron (SNP) | VAF 104/566 reads (18%) | catalogued as rs1164831768; called by muse, mutect2, varscan2
- ZNF773 | chr19:57513054 C>A | 3'Flank (SNP) | VAF 68/275 reads (25%) | called by muse, mutect2, varscan2
